Somatic mutation profile of tumor specimen 0DMOX9 from CCDI case PBCAHE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.8 years (5,777 days).
Specimen 0DMOX9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9576c36-ee0e-41af-9b8c-1cf4e50c6684.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMOXM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19eae158-62f1-4dba-a0a2-14a8c72971fa

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Del 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 199/1038 reads (19%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CFAP300 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 204/881 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SPAM1 | c.1486G>C p.V496L (on ENST00000223028; = p.X495_splice on NM_003117.5) | Missense Mutation (SNP) | VAF 242/1538 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GP6 | c.345G>A p.S115= | Silent (SNP) | VAF 82/400 reads (21%) | catalogued as rs772641061; called by muse, mutect2, varscan2
- BMP7 | c.-99C>G | 5'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
